Gene-level copy-number profile of tumor specimen HCM-BROD-0038-C41-86A from HCMI case HCM-BROD-0038-C41, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Bone, NOS; Age at diagnosis: 16.2 years (5,911 days).
Specimen HCM-BROD-0038-C41-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1fc2b241-3dd9-4a73-aa46-06da02eff927.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0038-C41-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,730 have no estimate.
https://portal.gdc.cancer.gov/files/146a11b8-8bef-4043-a63c-9020cc84c3ae

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,820; copy number 2: 17,407; copy number 3: 22,768; copy number 4: 8,773; copy number 5: 2,619; copy number 6: 2,129; copy number 7: 950; copy number 8: 202; copy number 9: 285; copy number 10: 417; copy number 11: 146; copy number 12: 118; copy number 13: 120; copy number 14: 66; copy number 15: 65; copy number 16: 5; copy number 17: 3.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,377 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:58,643,440–59,926,773, 18 genes, copy number 7: MYSM1, AL136985.3, JUN, LINC01135, AL136985.2, AL136985.1, LINC02777, LINC01358, PHBP3, AL592431.2, AL592431.1, HSD52, AC093424.1, FGGY, MIR4711, AL035416.1, HOOK1, CYP2J2.
- chr1:69,055,838–70,531,492, 20 genes, copy number 7: LINC01707, LINC02791, LINC01758, LRRC7, SGO1P1, AL117353.1, RN7SL538P, PIN1P1, LRRC7-AS1, LRRC40, RN7SL242P, SRSF11, AL353771.1, ANKRD13C, HHLA3, HHLA3-AS1, CTH, Metazoa_SRP, AL354872.1, CHORDC1P5.
- chr1:70,706,441–73,191,855, 24 genes, copy number 7–8: LINC01788, AL513285.1, PTGER3, AL031429.1, AL031429.2, ZRANB2-AS1, ZRANB2, MIR186, ZRANB2-AS2, AL358453.1, NEGR1, AL354949.1, AL359821.1, NEGR1-IT1, GDI2P2, AL513166.1, RPL31P12, AL583808.1, RNU6-1246P, LINC02796, LINC02797, AL732618.1, KRT8P21, RN7SKP19.
- chr1:73,635,216–75,161,533, 21 genes, copy number 7–8: LINC02238, RNA5SP50, AL591463.1, RNU4ATAC8P, LRRIQ3, FPGT, FPGT-TNNI3K, TNNI3K, AC093158.1, AC105271.1, LRRC53, ERICH3, ERICH3-AS1, AC135803.1, CRYZ, TYW3, AC133865.1, AC099786.3, AC099786.1, LHX8, AC099786.2.
- chr1:75,202,131–121,580,524, 809 genes, copy number 7–12 (within-gene range 7–13) (broad region; genes not listed).
- chr2:96,004,563–97,100,874, 45 genes, copy number 7: RN7SL210P, FAHD2CP, GPAT2, ADRA2B, ASTL, DUSP2, AC012307.1, STARD7, STARD7-AS1, TMEM127, CIAO1, SNRNP200, AC021188.1, ITPRIPL1, NCAPH, NEURL3, AC013270.1, ARID5A, KANSL3, FER1L5, LMAN2L, CNNM4, MIR3127, CNNM3-DT, CNNM3, ANKRD23, ANKRD39, SEMA4C, FAM178B, AC092636.1, Metazoa_SRP, RNA5SP101, AC079395.3, AC079395.2, AC079395.1, TRIM43CP, AC018892.1, AC018892.2, IGKV2OR2-1, IGKV2OR2-2, IGKV1OR2-3, GPAT2P2, FAHD2B, AC018892.3, RN7SL313P.
- chr2:97,281,356–97,291,849, 1 gene, copy number 11: AC159540.2.
- chr5:17,502,043–17,635,053, 20 genes, copy number 7: H3P17, H3P18, TAF11L3, TAF11L4, TAF11L5, TAF11L6, TAF11L7, AC233724.7, TAF11L8, TAF11L9, TAF11L10, AC233724.3, AC233724.6, TAF11L11, TAF11L12, H3P19, H3P20, H3P21, TAF11L13, TAF11L14.
- chr5:35,617,844–35,814,611, 1 gene, copy number 7 (within-gene range 6–7): SPEF2.
- chr5:35,678,484–35,827,018, 1 gene, copy number 7: AC137810.1.
- chr5:38,197,432–38,198,148, 1 gene, copy number 7: AC010338.1.
- chr6:36,697,826–36,737,986, 2 genes, copy number 7: RAB44, Z85996.1.
- chr6:36,871,870–37,819,218, 24 genes, copy number 7 (within-gene range 6–7): C6orf89, AL122034.1, PI16, MTCH1, FGD2, COX6A1P2, RPL12P2, PIM1, TMEM217, AL353579.1, TBC1D22B, AL096712.1, AL096712.2, RNF8, RN7SL273P, CMTR1, CCDC167, LINC02520, AL353597.2, AL353597.1, MIR4462, AL353597.3, MDGA1, AL121574.1.
- chr6:38,168,451–38,640,148, 1 gene, copy number 7 (within-gene range 2–7): BTBD9.
- chr6:38,481,692–38,588,529, 3 genes, copy number 7: BTBD9-AS1, Y_RNA, AL079341.1.
- chr6:39,329,990–39,725,408, 1 gene, copy number 10 (within-gene range 6–10): KIF6.
- chr6:39,553,811–54,266,280, 311 genes, copy number 7–14 (broad region; genes not listed).
- chr7:114,086,327–115,682,618, 15 genes, copy number 8: FOXP2, AC073626.2, AC073626.1, AC003992.1, RNA5SP238, MIR3666, MDFIC, LINC01393, LINC01392, RAC1P6, Y_RNA, POLR2DP2, SNORA25B, AC092590.1, AC093714.1.
- chr15:26,543,546–26,970,385, 6 genes, copy number 9–11: GABRB3, AC009878.1, AC011196.1, AC135999.1, GABRA5, TVP23BP1.
- chr15:28,881,667–29,118,315, 2 genes, copy number 13 (within-gene range 1–13): AC174469.1, APBA2.
- chr15:29,120,254–30,883,231, 63 genes, copy number 12–17 (broad region; genes not listed).
- chr15:67,521,131–69,461,806, 44 genes, copy number 7–16 (within-gene range 2–16): C15orf61, AC016355.1, MAP2K5, HNRNPA1P5, SKOR1, AC009292.2, AC009292.1, RNU6-1, AC022254.1, AC135628.1, PIAS1, AC107871.1, CALML4, CLN6, HMGN2P40, AC107871.2, FEM1B, ITGA11, CORO2B, CARS1P1, ANP32A, MIR4312, SPESP1, AC087639.1, AC087639.2, AC027088.1, NOX5, AC027088.5, AC027088.4, AC027088.3, EWSAT1, AC027088.2, GLCE, AC026992.2, AC026992.1, PAQR5, AC027237.4, AC027237.3, Y_RNA, KIF23, AC027237.1, RPLP1, U3, AC027237.2.
- chr15:69,564,724–69,565,790, 1 gene, copy number 11: AC100826.1.
- chr15:71,096,952–71,783,383, 1 gene, copy number 15 (within-gene range 2–15): THSD4.
- chr15:71,332,120–72,118,577, 10 genes, copy number 15 (within-gene range 2–15): AC064799.2, AC064799.1, AC108861.1, NR2E3, AC104938.1, MYO9A, RNA5SP399, AC022872.1, EIF5A2P1, RNU2-65P.
- chr15:75,903,876–76,905,444, 16 genes, copy number 13–15 (within-gene range 13–16): FBXO22, NRG4, AC027104.1, TMEM266, AC091100.1, ETFA, Metazoa_SRP, TYRO3P, AC027243.3, ISL2, AC027243.1, AC027243.2, SCAPER, AC090751.1, MIR3713, RN7SKP217.
- chr15:79,559,256–85,794,925, 192 genes, copy number 7–16 (broad region; genes not listed).
- chr15:86,079,973–87,029,052, 1 gene, copy number 7 (within-gene range 5–8): AGBL1.
- chr15:86,295,649–99,716,466, 279 genes, copy number 7–12 (within-gene range 2–12) (broad region; genes not listed).
- chr17:15,229,773–27,003,259, 383 genes, copy number 7–9 (broad region; genes not listed).
- chr19:31,797,666–32,073,809, 2 genes, copy number 7: LINC01837, LINC01533.
- chr19:32,243,965–34,229,515, 54 genes, copy number 7–8: RNA5SP472, ZNF507, AC007773.1, DPY19L3, PDCD5, ANKRD27, SNORA68B, RPS12P31, RN7SL789P, AC008474.1, RGS9BP, AC008736.1, NUDT19, AC008736.2, TDRD12, AC008805.1, SLC7A9, AC008805.2, RN7SKP22, CEP89, RPL31P60, FAAP24, RHPN2, AC008521.1, AC008521.2, GPATCH1, WDR88, LRP3, AC008738.1, AC008738.7, SLC7A10, AC008738.4, AC008738.6, AC008738.3, CEBPA, AC008738.5, CEBPA-DT, AC008738.2, RPS3AP50, AKR1B1P7, CEBPG, PEPD, AC010485.1, RPL21P131, CHST8, KCTD15, AC008556.1, RN7SL150P, AC016587.1, RPS4XP23, RPS4XP20, RPS4XP21, CHCHD2P3, LSM14A.
- chr19:35,704,558–35,745,445, 5 genes, copy number 7: ZBTB32, KMT2B, IGFLR1, AD000671.2, U2AF1L4.

Autosomal genes at a single copy (total copy number 1): 1,631. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
